Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H8, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H8-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Stomach cancer

GROSS:

Specimen submitted: Distal gastrectomy, fresh

Measurement:

Great curvature 14.3 cm
Lesser curvature 12.0 cm
Proximal resection margin 14.0 cm
Distal resection margin 4.8 cm
Duodenum 2.0 cm

Tumor location:

Stomach: Distal 1/3 (antrum), greater curvature
From proximal resection margin - 8.0 cm
From distal resection margin - 3.5 cm

Tumor size: 4.8 x 3.3 x 1.2 cm

Tumor type: EGC I

Gross serosal invasion: No

Gross photo: Present

Blocks

T1-4, TB, tumor and surrounding tissue x 5

A, antral mucosa x 1

NB, B, body mucosa x 2

P, proximal resection margin x 1

D, distal resection margin x 1

LN1-3, superior gastric lymph nodes x 3

LN4-6, inferior gastric lymph nodes x 3

LN7, '5' lymph node x 1

LN8, '6' lymph node x 1

LN9, '7' lymph node x 1

LN10, '8' lymph node x 1

LN11, '9' lymph node x 1

LN12, '11p' lymph node x 1

ICD-O-3

adenocarcinoma, tubular 8211/3

Site: Stomach, antrum C16.3

lw
9/27/12

MICROSCOPIC

<WHO histologic typing>

Adenocarcinoma, tubular, moderately differentiated

Depth of invasion:

T1: T1b-Submucosa lower 1/3 (SM3)

- over -

[page 2 of 3]
Margins:

Proximal resection margin: Uninvolved

Distal resection margin: Uninvolved

Lauren classification: Intestinal

Ming (Growth pattern) classification: Expanding

Lymphoid reaction: Present

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perinerve invasion: Absent

Polyps: Multinodular lesion in the distal antrum

Lymph node metastasis: Present

Distant metastasis: Cannot be assessed

Pathologic stage: pT1bN1MX

SPECIAL STAIN: Cresyl Violet stain reveals no H. pylori.

DIAGNOSIS:

Stomach, subtotal gastrectomy:

Adenocarcinoma, moderately differentiated, infiltrating
(early cancer)

Tubular adenoma with low grade dysplasia

Lymph node, perigastric, subtotal gastrectomy:

Superior gastric: No tumor present (0/28)

Inferior gastric: Metastatic carcinoma, primary in stomach (1/10)

Lymph node, regional, excision:

Labeled '5': No tumor present (0/1)

Labeled '6': No tumor present (0/14)

Labeled '7': No tumor present (0/2)

Labeled '8': No tumor present (0/5)

- over -

[page 3 of 3]
Labeled '9': No lymph node
Labeled '11p': No tumor present (0/2)

H/PA Discrepancy		X

RM

Source: NCI Genomic Data Commons file f97e9693-d13f-42f0-97d7-b99fb3d87c86 (TCGA-HU-A4H8.249F6B5F-89B9-4932-8B1F-183FE8E6126B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).